Somatic mutation profile of tumor specimen TCGA-2G-AAHC-01A (aliquot TCGA-2G-AAHC-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAHC, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 33.1 years (12,105 days).
Specimen TCGA-2G-AAHC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3861114-3651-47c8-aaee-6fac4c33076a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAHC-10A (Blood Derived Normal), aliquot TCGA-2G-AAHC-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48bb9ccc-d4de-4eac-a748-85983a0678ff

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 5'Flank 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRRG1 | c.407A>G p.D136G | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.202); catalogued as rs886248362; called by muse, varscan2
- TTN | c.73550G>T p.R24517I (on ENST00000591111; = p.R17093I on NM_003319.4) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | PolyPhen benign (0.003); catalogued as COSV100603858, COSV60303603; called by muse, mutect2
- CCDC102B | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- COL14A1 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- HACL1 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NISCH | c.2810A>G p.N937S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OR14A2 | c.661_663del p.S221del | In Frame Del (DEL) | VAF 8/71 reads (11%) | called by mutect2, pindel, varscan2
- RDH10 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.197); called by muse, mutect2
- THAP5 | c.1042C>A p.L348I (on ENST00000415914 / NM_001130475.3; = p.L306I on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BHLHE22 | c.939C>T p.G313= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- DENND2C | c.2625A>G p.A875= (on ENST00000393274 / NM_001256404.2; = p.A818= on NM_198459.4) | Silent (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2
- CDK11A | chr1:1725387 C>T | 5'Flank (SNP) | VAF 53/339 reads (16%) | catalogued as rs1015481774; called by muse, varscan2
- DNAJC5B | c.*3T>C | 3'UTR (SNP) | VAF 8/39 reads (21%) | catalogued as rs189431299; called by muse, mutect2, varscan2
